Surgical pathology report (de-identified scan), TCGA case TCGA-SC-A6LP, project TCGA-MESO (Mesothelioma), tissue source site Memorial Sloan Kettering, specimen TCGA-SC-A6LP-01A (Primary Tumor).

[page 1 of 2]
C&F ICD-O-3
Mesothelioma, diffuse
malignant biphasic NOS
9053/3

path
Mesothelioma, malignant
biphasic type w/epithelioid
and sarcomatoid components
(9052/3)
Code to highest 9052/3
Site @ Pleura C38.4
JW 7/5/13

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: M Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]

Clinical Diagnosis & History:
year old male with right pleural effusion - questionable mesothelioma

Specimens Submitted:
1: Right pleural biopsy (fs)
2: Right pleura biopsy

DIAGNOSIS:
1, 2. Right pleura; biopsy 1 (fs) and biopsy 2:
- Malignant mesothelioma, biphasic type, with epithelioid and
sarcomatoid components. See note.

Note: Immunostains show that the tumor cells are positive CK7, WT1 (focal)
and calretinin (focal), supporting the diagnosis. In this biopsy, the
epithelioid component represents 20% and sarcomatoid component represents
80% of the tumor.

Some of the immunohistochemistry and ISH tests were developed and their
performance characteristics were determined by the
They have not been cleared or approved by the US Food and Drug
Administration. The FDA has determined that such clearance or approval is
not necessary. These tests are used for clinical purposes. They should not
be regarded as investigational or for research. This laboratory is certified
under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as
qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

[page 2 of 2]
1). Received fresh and subsequently placed in formalin labeled "right pleural biopsy" is a 1.5 x 0.8 x 0.3 cm tan pink nodular fragment of rubbery tissue, which is submitted in toto for frozen section diagnosis, and the residue from frozen section is submitted for permanent.

Summary of sections:
FSC -- frozen section control

2) The specimen is received fresh, labeled "Right pleural biopsy" and consists of a 1.6 x 1.5 x 0.5 cm aggregate of soft, irregular to slightly nodular, tan-white tissue fragments. A representative section is submitted to TFS and the remaining specimen is submitted for permanent.

Summary of sections:
RS -- remaining specimen

Summary of Sections:
Part 1: Right pleural biopsy (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Right pleura biopsy

Block	Sect. Site	PCs
1	RS	6

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Mesothelioma
PERMANENT DIAGNOSIS: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Mesothelioma
PERMANENT DIAGNOSIS: Same

** End of Report **

Source: NCI Genomic Data Commons file 9b54a4c1-ed99-4af8-8668-6064f2864caf (TCGA-SC-A6LP.EB455F1C-C1BC-45CA-898B-051739D39D1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).